Gene-level copy-number profile of tumor specimen TCGA-AC-A2B8-01A from TCGA case TCGA-AC-A2B8, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 84.9 years (31,003 days).
Specimen TCGA-AC-A2B8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.abfdddc2-b118-4b4e-a283-f8cbc56730b4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A2B8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48f94f58-de61-4d49-8902-353574beed27

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 2: 2,608; copy number 3: 210; copy number 4: 51,393; copy number 5: 153; copy number 6: 1,862; copy number 7: 607; copy number 8: 1,419; copy number 10: 39; copy number 11: 1,472.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A2B8-01A-11D-A17C-01): tumor purity 0.53, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–2,926,689, 57 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,511 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:175,315,194–248,919,946, 1,472 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr19:5,558,167–6,370,242, 39 genes, copy number 10 (within-gene range 5–10): TINCR, SNRPEP4, SAFB2, SAFB, RPL36, MICOS13, HSD11B1L, LONP1, CATSPERD, PRR22, AC011499.1, DUS3L, NRTN, FUT6, FUT3, AC024592.2, FUT5, AC024592.3, NDUFA11, AC024592.1, AC104532.1, VMAC, AC104532.2, CAPS, RANBP3, AC011444.1, RFX2, AC011444.2, AC011444.4, AC011444.3, ACSBG2, AC011471.1, AC011471.4, MLLT1, AC011471.2, AC011471.3, ACER1, AC011491.3, CLPP.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
